Surgical pathology report (de-identified scan), TCGA case TCGA-24-1105, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1105-01A (Primary Tumor).

[page 1 of 5]
Patient Name:

DOB:

Accession:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Patient Name:

Address

Gender:

DOB:

Service:Gynecology

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Reported:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA WITH FOCAL CLEAR CELL FEATURES (SEE COMMENT)

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA INVOLVING TUBAL LYMPHATIC SPACES

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA WITH FOCAL CLEAR CELL FEATURES
- PARAOVARIAN ADHESIONS

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA, INVOLVING TUBAL FIMBRIA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA INVOLVING DEEP CERVICAL SOFT TISSUE

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- PROLIFERATIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

POSTERIOR CUL-DE-SAC, BIOPSY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

OMENTUM, OMENTECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA, 5 CM IN GREATEST DIMENSION

SPECIMEN LABELED "TUMOR," SITE NOT SPECIFIED, EXCISION

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

[page 2 of 5]
Patient Name:

DOB:

Accession:

LYMPH NODES, RIGHT PERIAORTIC, EXCISION

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA INVOLVING SEVEN OF SEVEN LYMPH NODES (7/7)
(SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my
personal
examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to O.R. to pick up 'right adnexa' consisting of an an adnexa, weighing 246 grams, and measuring 10.5 x 8.2 x 7.0 cm. Inked black and sectioned to show grey-white tissue, filling and replacing the ovary. Some areas are more solid, other more soft. There are also several cysts with hemorrhagic fluid and smooth internal lining, ranging from 1.0 x 0.6 to 4.0 x 1.6 cm. Solid and soft areas of cyst wall are frozen as FS. Rest for permanents. Tissue taken for tumor bank and ." by

FS: Ovary, right, oophorectomy

-"Adenocarcinoma, favor Mullerian origin," by

Microscopic Description and Comment:

Poorly differentiated papillary serous adenocarcinoma is present in both ovaries, omentum, fallopian tubes, deep cervical soft tissue, in the cul-de-sac biopsy, and in the separately submitted specimen labeled "tumor." In the ovary, a small portion of the tumor, less than 10%, exhibits clear cell differentiation. Seven of seven right para-aortic lymph nodes also contain metastatic adenocarcinoma. In addition, a large amount of papillary serous adenocarcinoma is present in fibrous tissue in the right para-aortic lymph node specimen. This may represent a totally replaced lymph node or a soft tissue metastasis. (D:

T:

History:

The patient is a year old woman with a right ovarian mass and elevation of CA-125 (~1900). Clinical diagnosis: Possible primary ovarian tumor. Operative procedure: Examination under anesthesia, explorative laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, omentectomy, and right periaortic lymph node dissection. (Note: a pelvic washing was sent to cytology.)

Specimen(s) Received:

A: RIGHT OVARY AND TUBE
B: LEFT OVARY AND TUBE
C: HYSTERECTOMY, NOS
D: POSTERIOR CUL DE SAC TUMOR
E: OMENTUM, ROUTINE
F: TUMOR
G: PERI AORTIC LYMPH NODE W/ FROZEN

Gross Description

Received are seven formalin-filled containers, each labeled with the patient's name. The first container is labeled "right adnexa (FS1/X)." It contains a white cassette, labeled FS, containing two pieces of grey-white ovarian tissue, measuring 1.7 x 1.4 x 0.2 and 1.4

[page 3 of 5]
Patient Name:

DOB:

x 1.2 x 0.2 cm, representing the remainder of the frozen section. Labeled A1 (FS). Also in the same container is a previously opened ovary, measuring 10.5 x 8.2 x 7.0 cm. The serosal surface has been inked black. The cut surface shows grey-white, focally soft and focally solid tissue without evidence of penetration through the serosal surface. There are numerous cysts identified with smooth internal linings and focal hemorrhage as well as focal attached intraluminal blood clots, ranging from 1.0 x 0.6 to 4.0 x 1.6 cm. No papillary protrusions are identified on the serosal surface. A portion of fallopian tube is identified, measuring 3 cm in length x 0.9 x 0.9 cm, with the fimbriated end measuring 1.9 x 0.7 x 0.4 cm. There is no evidence of invasion of the tumor into the fallopian tube. Labeled A2-A5 - ovary with solid areas; A6,A7 - ovary with soft areas; A8 - fallopian tube. Jar 3.

The second container is labeled "left adnexa." It contains a left ovary with fallopian tube, weighing 114.8 grams. The ovary measures 8 x 4.8 x 6 cm. It is composed of numerous cysts, ranging from 3.2 x 2.2 x 2.2 cm to 7.0 x 3.8 x 3.6 cm. Some of the ovarian cysts have a disrupted capsule. The serosal surface of the ovary is smooth and shiny and shows no papillary protrusions. The fallopian tube measures 6 cm in length x 0.5 x 0.5 cm with the fimbriated end, measuring 2.0 x 0.6 x 0.3 cm. The fallopian tube is surrounded by a smooth, glistening, unremarkable serosal surface. Ovary and fallopian tube are inked black. Sectioned to show cystic spaces, ranging from 1.0 x 1.0 to 3.0 x 2.8 cm. The largest spaces shows a papillary, soft, grey-yellow, friable tumor. Other areas of the ovary show solid, grey-white tissue. There is no evidence of tumor invasion to the serosal surface. Additionally, there is no evidence of invasion of the tumor in fallopian tube. Labeled B1-B5 - sections of cystic and solid areas; B6 - fallopian tube. Jar 2.

The third container is labeled "uterus and cervix." It contains a uterus weighing 100 grams and measuring 6.7 cm fundus to cervix, 4.6 cm lateral to lateral and 3.8 cm anterior posteriorly. The tan-white, glistening unremarkable ectocervix measures 5 cm in length x 4.7 cm in greatest dimension. The cervical os is slit-like. There is possible vaginal cuff present at the posterior portion of the ectocervix, measuring 2.6 cm in length x 0.9 in greatest dimension. The endocervical canal measures 2.8 cm in length x 1.2 cm and is lined by a tan-white, 0.2 cm thick unremarkable mucosa. The lower uterine segment, measures 1.7 cm in length. It is lined by smooth, glistening, tan-white, 0.2 cm thick unremarkable mucosa. The endometrial cavity measures 2.7 cm in length x 1.2 cm in maximum dimension. It is lined by a smooth, glistening, tan-white, 0.2 cm thick endometrium. No polypoid lesions or other distinct foci are present in the endometrium. The unremarkable myometrium ranges from 1.1 to 1.2 cm. The serosal surface is smooth and shiny with focal areas of tan-brown discoloration. No fibrous adhesions are found. Labeled C1 - anterior ecto- and endocervix; C2 - anterior endometrium; C3 - posterior ecto- and endocervix with possible vaginal cuff; C4 - posterior endometrium. Jar 3.

The fourth container is labeled "posterior cul de sac tumor." It contains approximately 9 grams of friable, grey-white, focally solid tissue. Labeled D1-D3. Jar 0.

The fifth container is labeled "omentum." It contains a portion of omentum, measuring 37 cm in length x 7.4 cm in maximum dimension. It shows multilobulated yellow adipose tissue with intersecting grey-white fibrovascular bundles. There are several grey-white, ill-defined, solid tumor deposits identified, ranging from 1.5 x 1.5 x 1.5 cm to 5.0 x 2.9 x 1.8 cm. These areas are sectioned to show ill-defined grey-white infiltrating tissue. Labeled E1,E2 - tumor deposits. Jar 2.

The sixth container is labeled "tumor." It contains an unoriented piece of yellow, adipose tissue, measuring 3 x 2 x 1 cm. It shows a smooth, glistening surface. It shows on its cut surface grey-white ill-defined tissue. Labeled F1,F2. Jar 0.

[page 4 of 5]
Patient Name:

DOB:

The seventh container is labeled "right periaortic lymph node." It contains several pieces of grey-white soft tissue, ranging from 1.7 x 1.0 x 0.4 cm to 4.2 x 2.7 x 1.7 cm. Sectioning shows grey-white ill-defined tissue without gross evidence of remaining lymph node parenchyma. Labeled G1,G2 - two sections of the largest piece of tissue (4.2 x 2.7 x 1.7 cm); G3-G6 - possible lymph nodes. Jar 1.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma with focal clear cell features (see comment)
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
5. Tumor IS NOT identified on the ovarian surface(s).
- 6 Tumor DOES invade the mesovarium.
7. Tumor DOES invade the adjacent fallopian tube.
8. Tumor DOES invade the pelvic soft tissue.
9. Tumor involvement of the pelvic peritoneum is PRESENT.
10. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
11. Metastatic involvement of the omentum is PRESENT.
12. The maximum dimension of tumor implants outside the true pelvis is 5.0 cm
13. Metastatic involvement of the uterine serosa is ABSENT.
14. Metastatic involvement of the endometrium is ABSENT.
15. Regional lymph node metastases are PRESENT.
16. The total number of regional lymph nodes examined is 7
17. The total number of metastatically-involved regional lymph nodes is 7
Extranodal extension by tumor metastases is PRESENT
18. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TMN Scheme	FIGO Scheme	Definition
T3c	IIIC	Macroscopic peritoneal
metastasis beyond true pelvis measuring > 2 cm		

THE REGIONAL LYMPH NODES are classified as:
N1 (Nodes contain metastatic tumor)

[page 5 of 5]
Patient Name: .

DOB:

THE STATUS OF DISTANT TUMOR SITES is classified as:
MX (Status cannot be assessed)

19. The FINAL AJCC/UICC/FIGO STAGE IS:
AJCC/UICC/FIGO

X

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file add81556-96eb-4ebe-a126-0a9c0b4ffece (TCGA-24-1105.DE593AFC-BC21-4183-94A6-B8BA9931B70F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).